Gene-level copy-number profile of tumor specimen TCGA-VQ-A91Y-01A from TCGA case TCGA-VQ-A91Y, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.8 years (24,774 days).
Specimen TCGA-VQ-A91Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.cdfb4d6c-62b1-4efa-bee0-566617c9ccf9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A91Y-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ce1d3179-9089-4cb8-a421-13d9439113ee

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 117; copy number 1: 121; copy number 2: 15,344; copy number 3: 14,426; copy number 4: 24,832; copy number 5: 3,350; copy number 6: 575; copy number 7: 237; copy number 8: 64; copy number 10: 118; copy number 11: 213; copy number 13: 17; copy number 14: 43; copy number 15: 112; copy number 16: 129; copy number 17: 27; copy number 18: 65; copy number 23: 5; copy number 32: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A91Y-01A-11D-A40Z-01): tumor purity 0.42, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:62,533,681–62,662,829, 1 gene (within-gene range 0–2): AC092155.1.
- chr2:62,673,851–63,197,037, 11 genes: EHBP1, Y_RNA, AC092567.2, AC092567.1, RPS20P9, AC007098.1, OTX1, AC009501.1, AC009501.2, RPL27P5, DBIL5P2.
- chr2:63,168,600–63,233,577, 2 genes: Metazoa_SRP, MTFR2P1.
- chr4:90,838,903–90,839,037, 1 gene: TMSB4XP8.
- chr17:11,241,213–11,564,063, 1 gene (within-gene range 0–2): SHISA6.
- chr17:11,598,470–12,215,267, 10 genes: DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2.
- chr17:14,705,076–15,052,276, 7 genes: RPS18P12, AC013248.1, AC005863.1, LINC02096, RPL23AP76, AC005772.1, CDRT7.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 736 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–146,237,807, 106 genes, copy number 11 (broad region; genes not listed).
- chr1:149,782,671–151,909,637, 129 genes, copy number 16 (broad region; genes not listed).
- chr1:152,985,231–154,155,116, 79 genes, copy number 15 (broad region; genes not listed).
- chr11:70,187,788–70,385,312, 9 genes, copy number 10 (within-gene range 5–10): ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3.
- chr20:42,685,404–54,651,169, 302 genes, copy number 10–18 (broad region; genes not listed).
- chr20:55,408,898–60,083,872, 110 genes, copy number 11–32 (broad region; genes not listed).
- chr20:60,308,474–60,308,567, 1 gene, copy number 14: MIR646.

Autosomal genes at a single copy (total copy number 1): 121. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
